Surgical pathology report (de-identified scan), TCGA case TCGA-CH-5748, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site Indivumed, specimen TCGA-CH-5748-01A (Primary Tumor).

Diagnosis

1. and 3. Tumor-free pelvic lymph nodes on both sides.

2. Tumor-free pelvic fibrolipomatous tissue.

4. Prostate with extensive infiltrates of an adenocarcinoma. Gleason score 3+4.

Tumor infiltration of both lobes from the apex to the base, somewhat more extensive on the right than on the left.

Apical areas show tumor infiltration of the periprostatic tissue, extending in parts to the margin.

Tumor-free seminal vesicles.

5. Partially resected right seminal vesicle tumor-free.

Stage pT3a G3 N0 R1.

TCGA-CH-5748

Source: NCI Genomic Data Commons file ee4fe705-4d1d-4f99-a2eb-795bca2f1507 (TCGA-CH-5748.7D2D5D7D-481B-445D-8505-42564E11FCE4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).